Somatic mutation profile of cancer-model specimen HCM-CSHL-0141-C18-85A (3D Organoid; aliquot HCM-CSHL-0141-C18-85A-01D-A77E-36), derived from the primary tumor of HCMI case HCM-CSHL-0141-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 67.2 years (24,563 days).
Specimen HCM-CSHL-0141-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 25ca992b-37eb-49da-93ab-dfa13678ae51.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0141-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0141-C18-10A-01D-A77E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f03b826a-e5c1-4c5d-9884-4c05e8971531

The open-access MAF lists 169 somatic variants for this specimen: 111 protein-altering or splice-affecting, 43 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 94, Silent 43, Nonsense Mutation 10, Intron 7, Splice Region 4, 3'UTR 3, RNA 2, 5'Flank 2, Frame Shift Ins 1, 3'Flank 1, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 227/227 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs193920817, COSV52660939, COSV52789715, COSV53470581; ClinVar: conflicting interpretations of pathogenicity / uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ABI3BP | c.1507G>A p.G503S | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs561424272, COSV52546271; called by muse, mutect2, varscan2
- AC018630.4 | c.28C>A p.P10T | Missense Mutation (SNP) | VAF 31/120 reads (26%) | PolyPhen benign (0.018); catalogued as COSV101115506; called by muse, mutect2, varscan2
- ADGRV1 | c.2596C>T p.R866W | Missense Mutation (SNP) | VAF 137/188 reads (73%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.927); catalogued as rs200389929, COSV67983288; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AFF3 | c.2792C>T p.T931M | Missense Mutation (SNP) | VAF 121/289 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.039); catalogued as rs373018231; called by muse, mutect2, varscan2
- APC | c.2557G>T p.E853* | Nonsense Mutation (SNP) | VAF 122/367 reads (33%) | catalogued as COSV57347085, COSV57378777; called by muse, mutect2, varscan2
- APC | c.4087A>T p.K1363* | Nonsense Mutation (SNP) | VAF 138/211 reads (65%) | catalogued as COSV57337694, COSV57379285; called by muse, mutect2, varscan2
- ARMH4 | c.1706G>A p.G569E | Missense Mutation (SNP) | VAF 109/393 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99957442; called by muse, mutect2, varscan2
- ATP2A1 | c.2944G>T p.E982* | Nonsense Mutation (SNP) | VAF 299/952 reads (31%) | catalogued as CM1411191, COSV62869021; called by muse, mutect2, varscan2
- ATP8B4 | c.2857C>T p.R953C | Missense Mutation (SNP) | VAF 152/263 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs749142543, COSV52710941; called by muse, mutect2, varscan2
- BCL2L14 | c.396G>T p.R132S | Missense Mutation (SNP) | VAF 117/224 reads (52%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.997); catalogued as rs767369919; called by muse, mutect2, varscan2
- BMP7 | c.509C>T p.T170M | Missense Mutation (SNP) | VAF 462/611 reads (76%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); catalogued as rs371762840; called by muse, mutect2, varscan2
- BSN | c.8513C>T p.T2838M | Missense Mutation (SNP) | VAF 58/327 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs546341531; called by muse, mutect2, varscan2
- CACNA1A | c.890G>T p.G297V | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64195180; called by muse, mutect2, varscan2
- CACNA1H | c.622C>T p.R208C | Missense Mutation (SNP) | VAF 34/544 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs758015873, COSV61985841; called by muse, mutect2
- CFAP410 | c.143+8G>A | Splice Region (SNP) | VAF 55/218 reads (25%) | catalogued as rs372854948; called by muse, mutect2, varscan2
- CMYA5 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 85/234 reads (36%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.08); catalogued as rs750047220; called by muse, mutect2, varscan2
- CNTNAP3 | c.1987G>A p.A663T | Missense Mutation (SNP) | VAF 209/840 reads (25%) | SIFT tolerated (0.53); PolyPhen benign (0.015); catalogued as rs769642592; called by muse, mutect2, varscan2
- CPEB3 | c.1966G>A p.V656I | Missense Mutation (SNP) | VAF 123/376 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.177); catalogued as rs767243674; called by muse, mutect2, varscan2
- DENND2A | c.1939G>A p.G647S | Missense Mutation (SNP) | VAF 56/224 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs938952428, COSV52052029; called by muse, mutect2
- DISP3 | c.3370G>A p.E1124K | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.99); catalogued as rs1359184018, COSV53829251; called by muse, mutect2, varscan2
- DNAJC7 | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 30/446 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); catalogued as rs1555647599, COSV57269035; called by muse, mutect2
- ELP5 | c.610C>T p.R204W | Missense Mutation (SNP) | VAF 92/92 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs762988971, COSV100598184; called by muse, mutect2, varscan2
- EYA2 | c.754C>T p.R252W | Missense Mutation (SNP) | VAF 63/412 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1416566553; called by muse, mutect2, varscan2
- FAM47A | c.1234C>T p.R412C | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs756452001, COSV60493630; called by muse, mutect2, varscan2
- FOXA2 | c.1351C>T p.R451W (on ENST00000377115 / NM_153675.3; = p.R457W on NM_021784.5) | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65796127; called by muse, mutect2, varscan2
- GTPBP2 | c.613C>T p.R205W | Missense Mutation (SNP) | VAF 178/520 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766935105; called by muse, mutect2, varscan2
- HCN2 | c.1873G>A p.D625N | Missense Mutation (SNP) | VAF 166/307 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.366); catalogued as rs750444405; called by muse, mutect2, varscan2
- HEPHL1 | c.2410C>T p.R804* | Nonsense Mutation (SNP) | VAF 20/134 reads (15%) | catalogued as rs185758554, COSV59890303; called by muse, mutect2, varscan2
- HLA-A | c.73+1G>C p.X25_splice | Splice Site (SNP) | VAF 53/109 reads (49%) | catalogued as COSV100954397; called by muse, mutect2, varscan2
- HOXD3 | c.782C>T p.S261L | Missense Mutation (SNP) | VAF 87/471 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs776045427; called by muse, mutect2, varscan2
- HSPG2 | c.7165G>A p.G2389S | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs765181959; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IKZF1 | c.1108G>A p.V370M | Missense Mutation (SNP) | VAF 202/932 reads (22%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.909); catalogued as rs779769920, COSV100498915; called by muse, mutect2, varscan2
- INVS | c.166G>A p.V56M | Missense Mutation (SNP) | VAF 125/323 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.582); catalogued as rs778036236, COSV52437949, COSV52447482; called by muse, mutect2, varscan2
- IRX6 | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs777983442, COSV51859093; called by muse, mutect2, varscan2
- ITGBL1 | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 119/567 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.394); catalogued as rs763790775; called by muse, mutect2, varscan2
- KCNA4 | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 62/224 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as rs777488025, COSV100068823; called by muse, mutect2, varscan2
- KLF3 | c.907C>T p.R303W | Missense Mutation (SNP) | VAF 72/115 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.295); catalogued as rs1472409063, COSV54711385; called by muse, mutect2, varscan2
- KY | c.760G>A p.G254S | Missense Mutation (SNP) | VAF 130/254 reads (51%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.51); catalogued as rs563164206, COSV101414995; called by muse, mutect2, varscan2
- LBH | c.235C>T p.R79W | Missense Mutation (SNP) | VAF 116/353 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1436120090; called by muse, mutect2, varscan2
- LRRTM1 | c.1178C>T p.T393M | Missense Mutation (SNP) | VAF 73/226 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.165); catalogued as rs917603256, COSV99703058; called by muse, mutect2, varscan2
- MAPT | c.1622C>T p.T541M (on ENST00000262410 / NM_001377265.1; = p.T149M on NM_005910.5) | Missense Mutation (SNP) | VAF 108/447 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.93); catalogued as rs964226257, COSV52248065; called by muse, mutect2, varscan2
- MARS1 | c.1126C>T p.R376* | Nonsense Mutation (SNP) | VAF 134/553 reads (24%) | catalogued as rs150674269; called by muse, mutect2, varscan2
- MEP1A | c.901G>T p.D301Y | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1250909280; called by muse, mutect2, varscan2
- MYO9B | c.1033G>T p.V345F | Missense Mutation (SNP) | VAF 26/384 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV101261424; called by muse, mutect2
- NDN | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 12/276 reads (4%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.068); catalogued as COSV59358224; called by muse, mutect2
- NLRP14 | c.2179C>A p.H727N | Missense Mutation (SNP) | VAF 74/221 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0.006); catalogued as rs1348554410; called by muse, mutect2, varscan2
- NLRP7 | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 96/344 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs374600785; called by muse, mutect2, varscan2
- NPAS4 | c.1722G>T p.L574F | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1171011062, COSV60652272; called by muse, mutect2, varscan2
- NPHP3 | c.2795A>C p.N932T | Missense Mutation (SNP) | VAF 154/305 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs1560002446; called by muse, mutect2, varscan2
- NR5A2 | c.979C>T p.Q327* (on ENST00000367362 / NM_205860.3; = p.Q281* on NM_003822.5) | Nonsense Mutation (SNP) | VAF 182/598 reads (30%) | catalogued as rs1206691380, COSV52653498; called by muse, mutect2, varscan2
- OR52L1 | c.487G>A p.G163R | Missense Mutation (SNP) | VAF 56/239 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.111); catalogued as rs769350807, COSV59988162; called by muse, mutect2, varscan2
- PCARE | c.3026G>A p.R1009H | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs200394246, COSV99045269; called by muse, mutect2, varscan2
- PCDHA6 | c.1603G>A p.V535M | Missense Mutation (SNP) | VAF 489/1531 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1262192253; called by muse, mutect2, varscan2
- PCDHA7 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 427/709 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1554134406, COSV65342182; called by muse, mutect2, varscan2
- PON3 | c.188C>A p.A63D | Missense Mutation (SNP) | VAF 137/614 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55698045; called by muse, mutect2, varscan2
- PRSS38 | c.764G>A p.R255H | Missense Mutation (SNP) | VAF 99/301 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs147849633; called by muse, mutect2, varscan2
- PSTPIP1 | c.1180G>A p.D394N | Missense Mutation (SNP) | VAF 90/338 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.057); catalogued as rs377006780; called by muse, mutect2, varscan2
- RASGRF1 | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 16/312 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); catalogued as COSV69181873; called by muse, mutect2
- RGL3 | c.1813C>T p.P605S | Missense Mutation (SNP) | VAF 53/235 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs374802887; called by muse, mutect2, varscan2
- RIMS1 | c.3796C>A p.R1266S | Missense Mutation (SNP) | VAF 78/214 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs1359398086; called by muse, mutect2, varscan2
- RIPOR3 | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 73/389 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs1029273818; called by muse, mutect2, varscan2
- ROBO1 | c.1859C>T p.A620V | Missense Mutation (SNP) | VAF 60/145 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0.017); catalogued as COSV101458641; called by muse, mutect2, varscan2
- SBK2 | c.865C>T p.R289C | Missense Mutation (SNP) | VAF 73/155 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.938); catalogued as rs781195404; called by muse, mutect2, varscan2
- SCX | c.418G>A p.G140R | Missense Mutation (SNP) | VAF 181/754 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.372); catalogued as rs1248659763; called by muse, mutect2, varscan2
- SENP6 | c.2749G>A p.D917N | Missense Mutation (SNP) | VAF 41/151 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.085); catalogued as rs560237458; called by muse, mutect2, varscan2
- SLC15A1 | c.903C>T p.G301= | Splice Region (SNP) | VAF 32/520 reads (6%) | catalogued as rs1159478484; called by muse, mutect2
- SLC4A9 | c.2444G>A p.G815D (on ENST00000507527 / NM_001258428.2; = p.G791D on NM_031467.3) | Missense Mutation (SNP) | VAF 108/185 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769862352; called by muse, mutect2, varscan2
- SLC6A20 | c.1718C>T p.A573V | Missense Mutation (SNP) | VAF 59/222 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs777908628, COSV100653839; called by muse, mutect2, varscan2
- SLC9A3 | c.1244G>A p.R415H | Missense Mutation (SNP) | VAF 172/494 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1327970675, COSV53804549; called by muse, mutect2, varscan2
- SLCO3A1 | c.94_96del p.K32del | In Frame Del (DEL) | VAF 40/151 reads (26%) | catalogued as rs1477752440; called by pindel, varscan2
- SMAD4 | c.290G>A p.R97H | Missense Mutation (SNP) | VAF 116/118 reads (98%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs1555685159, COSV61685150; ClinVar: uncertain significance; called by muse, varscan2
- STK11IP | c.2656C>T p.R886C | Missense Mutation (SNP) | VAF 62/276 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs779471681, COSV55253251; called by muse, mutect2, varscan2
- STON1 | c.1621G>A p.V541M | Missense Mutation (SNP) | VAF 146/224 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs763696544; called by muse, mutect2, varscan2
- TLN1 | c.2746C>T p.R916C | Missense Mutation (SNP) | VAF 212/876 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as rs574795385, COSV59204317; called by muse, mutect2, varscan2
- TP63 | c.109C>T p.R37* | Nonsense Mutation (SNP) | VAF 143/294 reads (49%) | catalogued as rs147340040; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRIP12 | c.5680C>T p.R1894W | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1480116316; called by muse, mutect2
- USP29 | c.146G>T p.R49I | Missense Mutation (SNP) | VAF 44/220 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); catalogued as rs1568455663, COSV99572122; called by muse, mutect2, varscan2
- USP34 | c.7124G>A p.R2375H | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.409); catalogued as rs1008915384, COSV68406315; called by muse, mutect2, varscan2
- WSCD2 | c.634C>T p.R212C | Missense Mutation (SNP) | VAF 277/548 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as COSV54579204, COSV99774807; called by muse, mutect2, varscan2
- ZIC5 | c.1736C>T p.P579L | Missense Mutation (SNP) | VAF 76/341 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs769045432, COSV99940754; called by muse, mutect2, varscan2
- ZNF329 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 24/197 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.439); catalogued as rs751785719, COSV63772333, COSV63772570; called by muse, mutect2, varscan2
- ADAM9 | c.1234T>C p.Y412H | Missense Mutation (SNP) | VAF 52/654 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- AMOT | c.1544T>C p.L515P (on ENST00000371959 / NM_001113490.1; = p.L106P on NM_133265.3) | Missense Mutation (SNP) | VAF 122/124 reads (98%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); called by muse, mutect2, varscan2
- ATP2A3 | c.1157G>T p.G386V | Missense Mutation (SNP) | VAF 11/267 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- CCDC138 | c.40G>T p.V14L | Missense Mutation (SNP) | VAF 11/336 reads (3%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.003); called by muse, mutect2
- CCDC157 | c.1046-7G>T | Splice Region (SNP) | VAF 87/149 reads (58%) | called by muse, mutect2, varscan2
- COL12A1 | c.2510C>A p.A837E | Missense Mutation (SNP) | VAF 98/297 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- DBX2 | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 83/261 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- DYNC1I1 | c.1595C>T p.A532V | Missense Mutation (SNP) | VAF 70/278 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- EPB41L1 | c.1925A>G p.E642G | Missense Mutation (SNP) | VAF 97/489 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ESD | c.121G>T p.E41* | Nonsense Mutation (SNP) | VAF 23/138 reads (17%) | called by muse, mutect2, varscan2
- FLG2 | c.3520G>T p.G1174C | Missense Mutation (SNP) | VAF 68/193 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- FN1 | c.4015T>C p.S1339P | Missense Mutation (SNP) | VAF 165/534 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- HPS5 | c.1321C>T p.H441Y (on ENST00000349215 / NM_181507.2; = p.H327Y on NM_007216.4) | Missense Mutation (SNP) | VAF 48/140 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LCNL1 | c.365C>T p.P122L | Missense Mutation (SNP) | VAF 226/526 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- LRFN5 | c.531T>A p.S177R | Missense Mutation (SNP) | VAF 62/93 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- MLLT10 | c.2926C>T p.Q976* (on ENST00000307729 / NM_001195626.3; = p.Q992* on NM_004641.3) | Nonsense Mutation (SNP) | VAF 42/177 reads (24%) | called by muse, mutect2, varscan2
- NCAN | c.3277C>A p.H1093N | Missense Mutation (SNP) | VAF 147/553 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- OR51A7 | c.456C>A p.S152R | Missense Mutation (SNP) | VAF 47/215 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- OR52J3 | c.720C>A p.S240R | Missense Mutation (SNP) | VAF 35/138 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- PBX1 | c.349G>A p.V117M | Missense Mutation (SNP) | VAF 134/389 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PCDHGB1 | c.152A>T p.D51V | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- PIP5K1C | c.244G>T p.A82S | Missense Mutation (SNP) | VAF 49/477 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- PLPPR5 | c.307dup p.T103Nfs*54 | Frame Shift Ins (INS) | VAF 31/126 reads (25%) | called by mutect2, pindel, varscan2
- PTPRH | c.2462C>A p.A821E | Missense Mutation (SNP) | VAF 69/254 reads (27%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.584); called by muse, mutect2, varscan2
- RNF215 | c.671G>A p.C224Y | Missense Mutation (SNP) | VAF 39/137 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- STAB1 | c.4764G>A p.E1588= | Splice Region (SNP) | VAF 45/243 reads (19%) | called by muse, mutect2, varscan2
- TRIM49B | c.501C>A p.C167* | Nonsense Mutation (SNP) | VAF 109/326 reads (33%) | called by muse, mutect2, varscan2
- ZNF484 | c.706C>A p.Q236K | Missense Mutation (SNP) | VAF 69/310 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- ZNF528 | c.1682G>T p.C561F | Missense Mutation (SNP) | VAF 41/162 reads (25%) | SIFT tolerated (0.57); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- A2M | c.246C>T p.D82= | Silent (SNP) | VAF 83/179 reads (46%) | catalogued as rs752368777, COSV59382553; called by muse, mutect2, varscan2
- ADAM33 | c.1182C>T p.R394= | Silent (SNP) | VAF 66/322 reads (20%) | called by muse, mutect2, varscan2
- CD19 | c.1143G>A p.P381= | Silent (SNP) | VAF 102/260 reads (39%) | catalogued as rs757976340; called by muse, mutect2, varscan2
- CLU | c.705C>T p.Y235= | Silent (SNP) | VAF 324/688 reads (47%) | catalogued as rs751114860, COSV57067036; ClinVar: likely benign; called by muse, mutect2, varscan2
- COPS7B | c.433C>T p.L145= | Silent (SNP) | VAF 115/570 reads (20%) | called by muse, mutect2, varscan2
- DAB2IP | c.900G>A p.S300= (on ENST00000408936; = p.S272= on NM_032552.3) | Silent (SNP) | VAF 219/394 reads (56%) | catalogued as rs202119015, COSV52265730; called by muse, mutect2, varscan2
- DHRS4 | c.87G>T p.P29= | Silent (SNP) | VAF 64/496 reads (13%) | catalogued as rs758077923; called by muse, mutect2, varscan2
- EFCAB1 | c.351C>T p.D117= | Silent (SNP) | VAF 72/136 reads (53%) | catalogued as rs747636083, COSV50617990; called by muse, mutect2, varscan2
- FAT4 | c.12018G>T p.T4006= | Silent (SNP) | VAF 79/171 reads (46%) | called by muse, mutect2, varscan2
- FLG | c.9522C>T p.S3174= | Silent (SNP) | VAF 86/421 reads (20%) | catalogued as rs1053812081; called by muse, mutect2, varscan2
- FLG | c.8550C>T p.G2850= | Silent (SNP) | VAF 149/2124 reads (7%) | catalogued as rs376468454; called by muse, mutect2
- GAS2L3 | c.1620C>T p.S540= | Silent (SNP) | VAF 79/305 reads (26%) | catalogued as rs202229990; called by muse, mutect2, varscan2
- GRIN2A | c.2196C>T p.A732= | Silent (SNP) | VAF 143/192 reads (74%) | catalogued as rs748323416, COSV100411448; called by muse, mutect2, varscan2
- GTF2E1 | c.378C>T p.S126= | Silent (SNP) | VAF 39/162 reads (24%) | catalogued as rs1202594049; called by muse, mutect2, varscan2
- IGF1R | c.3870G>A p.P1290= | Silent (SNP) | VAF 77/273 reads (28%) | catalogued as rs138888653, COSV51342228; called by muse, mutect2, varscan2
- KIF26B | c.642C>T p.Y214= | Silent (SNP) | VAF 94/299 reads (31%) | catalogued as rs751658390, COSV68572319; called by muse, mutect2, varscan2
- LAMA5 | c.11022C>T p.P3674= | Silent (SNP) | VAF 154/832 reads (19%) | catalogued as rs764906504, COSV99439113; called by muse, mutect2, varscan2
- LARGE1 | c.1626C>T p.P542= | Silent (SNP) | VAF 238/380 reads (63%) | catalogued as rs775137166, COSV100506283; called by muse, mutect2, varscan2
- LRRTM1 | c.435G>A p.S145= | Silent (SNP) | VAF 110/401 reads (27%) | catalogued as rs761682948, COSV54445071, COSV99701623; called by muse, mutect2, varscan2
- MORN1 | c.297C>T p.G99= | Silent (SNP) | VAF 97/383 reads (25%) | catalogued as rs779763554; called by muse, mutect2, varscan2
- NPEPL1 | c.1119G>A p.G373= | Silent (SNP) | VAF 19/125 reads (15%) | called by muse, mutect2, varscan2
- OR2H1 | c.279G>T p.L93= | Silent (SNP) | VAF 100/354 reads (28%) | called by muse, mutect2, varscan2
- OR4D1 | c.441C>T p.A147= | Silent (SNP) | VAF 91/383 reads (24%) | catalogued as rs372813872; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.915C>T p.R305= (on ENST00000259318 / NM_001136562.3; = p.R536= on NM_007203.5) | Silent (SNP) | VAF 72/289 reads (25%) | catalogued as rs770245489, COSV52178299; called by muse, varscan2
- PCDHB12 | c.1992C>T p.D664= | Silent (SNP) | VAF 123/480 reads (26%) | catalogued as rs534329232; called by mutect2, varscan2
- PPFIA2 | c.792C>T p.T264= | Silent (SNP) | VAF 84/166 reads (51%) | catalogued as rs377170926, COSV61061855; called by muse, mutect2, varscan2
- PPP1R13B | c.990G>A p.T330= | Silent (SNP) | VAF 104/149 reads (70%) | catalogued as rs376013196; called by muse, mutect2, varscan2
- QRICH2 | c.3954G>A p.E1318= | Silent (SNP) | VAF 92/295 reads (31%) | called by muse, mutect2, varscan2
- RAB3B | c.651C>T p.C217= | Silent (SNP) | VAF 27/89 reads (30%) | called by muse, mutect2
- RPL3 | c.594C>T p.R198= | Silent (SNP) | VAF 178/555 reads (32%) | catalogued as rs368072771; called by muse, mutect2, varscan2
- RYR1 | c.11940G>C p.A3980= | Silent (SNP) | VAF 456/938 reads (49%) | catalogued as rs750022861, COSV62098494; ClinVar: likely benign; called by muse, mutect2, varscan2
- SAC3D1 | c.18G>A p.L6= | Silent (SNP) | VAF 156/305 reads (51%) | called by muse, mutect2, varscan2
- SETBP1 | c.2721C>T p.S907= | Silent (SNP) | VAF 31/146 reads (21%) | catalogued as rs148632511; called by muse, mutect2, varscan2
- SLC4A1 | c.1755C>T p.A585= | Silent (SNP) | VAF 352/591 reads (60%) | called by muse, mutect2, varscan2
- SLC6A13 | c.1203G>A p.A401= | Silent (SNP) | VAF 83/362 reads (23%) | catalogued as rs140923338; called by muse, mutect2, varscan2
- SPAG8 | c.312C>T p.H104= | Silent (SNP) | VAF 63/367 reads (17%) | called by muse, mutect2, varscan2
- SSTR5 | c.684G>T p.V228= | Silent (SNP) | VAF 60/175 reads (34%) | called by muse, mutect2, varscan2
- SUPT16H | c.1545A>T p.P515= | Silent (SNP) | VAF 29/120 reads (24%) | called by muse, mutect2, varscan2
- TENM2 | c.2950C>A p.R984= (on ENST00000518659 / NM_001122679.2; = p.R752= on NM_001080428.3) | Silent (SNP) | VAF 73/249 reads (29%) | catalogued as COSV69138929; called by muse, mutect2, varscan2
- TMEM266 | c.837G>A p.A279= | Silent (SNP) | VAF 77/250 reads (31%) | catalogued as rs1254929804; called by muse, mutect2, varscan2
- TTC21A | c.969C>T p.I323= | Silent (SNP) | VAF 87/162 reads (54%) | catalogued as rs369704736; called by muse, mutect2, varscan2
- UGT1A1 | c.21C>T p.G7= | Silent (SNP) | VAF 177/375 reads (47%) | catalogued as rs780253764, COSV100530873; called by muse, mutect2, varscan2
- ZNF280D | c.2646G>A p.K882= | Silent (SNP) | VAF 80/217 reads (37%) | catalogued as rs1273219633; called by muse, mutect2, varscan2
- CLU | c.*591G>T | 3'UTR (SNP) | VAF 84/400 reads (21%) | called by muse, mutect2, varscan2
- CYP4F3 | c.199-1738G>T | Intron (SNP) | VAF 21/90 reads (23%) | called by muse, mutect2, varscan2
- DCAF13 | chr8:103415213 G>A | 5'Flank (SNP) | VAF 102/211 reads (48%) | called by muse, mutect2, varscan2
- DCHS2 | n.7267C>A | RNA (SNP) | VAF 147/242 reads (61%) | called by muse, mutect2, varscan2
- ERBB2 | c.1022-83G>A | Intron (SNP) | VAF 88/168 reads (52%) | called by muse, mutect2, varscan2
- GPSM1 | chr9:136327035 C>T | 5'Flank (SNP) | VAF 23/73 reads (32%) | catalogued as rs1345141139; called by muse, mutect2, varscan2
- KCNQ1 | c.*148G>A | 3'UTR (SNP) | VAF 28/100 reads (28%) | called by muse, mutect2, varscan2
- LINC01583 | n.1403C>G | RNA (SNP) | VAF 62/214 reads (29%) | called by muse, mutect2, varscan2
- MGAM2 | c.5138-302G>A | Intron (SNP) | VAF 34/180 reads (19%) | catalogued as rs904149283; called by muse, mutect2, varscan2
- NAV3 | c.2024-13005C>T | Intron (SNP) | VAF 46/319 reads (14%) | catalogued as rs867606698, COSV57106168; called by muse, mutect2, varscan2
- PCDHB6 | chr5:141157703 G>T | 3'Flank (SNP) | VAF 359/1320 reads (27%) | called by muse, mutect2, varscan2
- PDE7B | c.711+118C>T | Intron (SNP) | VAF 75/245 reads (31%) | catalogued as rs750908439, COSV100367475; called by muse, mutect2, varscan2
- ROBO2 | c.3554+56dup | Intron (INS) | VAF 16/132 reads (12%) | called by mutect2, varscan2
- SCRIB | c.643-28C>T | Intron (SNP) | VAF 86/377 reads (23%) | catalogued as rs559575765, COSV100252686; called by muse, mutect2, varscan2
- TP53TG3D | c.*187G>A | 3'UTR (SNP) | VAF 198/1060 reads (19%) | called by muse, mutect2, varscan2
